Surgical pathology report (de-identified scan), TCGA case TCGA-90-6837, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-90-6837-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]
Final Pathologic Diagnosis:

- A. Chest wall margin (FS), resection:
Negative for malignancy.
Frozen section diagnosis is confirmed.
- B. Pleural margin (FS), resection:
Negative for malignancy.
Frozen section diagnosis is confirmed.
- C. Right upper lobe bronchial margin (FS), resection:
Negative for malignancy.
Frozen section diagnosis is confirmed.
- D. Lung, right upper lobe and right middle lobe, resection:
Invasive squamous cell carcinoma.

Specimen: Lung, right upper lobe and right middle lobe

Procedure: Bilobectomy

Specimen laterality: Right

Tumor site: Upper lobe and middle lobe

Specimen integrity: Intact

Tumor size (greatest dimension): 7.5 cm

Tumor focality: Unifocal

Tumor histologic type: Invasive squamous cell carcinoma

Tumor grade: Moderately differentiated

Visceral pleura invasion: Not identified (tumor abuts but does not perforate visceral pleura)

Tumor Extension: Not identified (tumor abuts but does not perforate visceral pleura)

Margins:

Bronchial: Uninvolved by invasive carcinoma

Vascular: Uninvolved by invasive carcinoma

Parenchymal: Not applicable

Parietal pleural: Uninvolved by invasive carcinoma

Chest wall: Uninvolved by invasive carcinoma

Other attached tissue margin: Not applicable

If all margins uninvolved by invasive carcinoma:

Distance of invasive carcinoma from closest margin: <1 mm

Specify margin: Parietal pleura

Treatment effect: Not applicable

Lymph-vascular invasion: Not definitively identified

Pathologic staging (pTNM):

TNM Descriptors: None known

Primary tumor: pT3

Regional lymph nodes: pN0

[page 2 of 5]
Number examined: 26 (the lymph node count includes parts D, E, F, G, H, I and J)

Number involved: 0

Distant metastasis: pMX

Additional pathologic findings: Emphysematous changes

E. Level II lymph node (FS), resection:

One lymph node, negative for metastatic malignancy (0/1).

Frozen section diagnosis is confirmed.

F. Inferior pulmonary lymph node, resection:

One lymph node, negative for metastatic malignancy (0/1).

G. 4R lower paratracheal lymph node, resection: Three lymph nodes, negative for metastatic malignancy (0/3).

H. 2R upper paratracheal lymph nodes, resection:

Seven lymph nodes, negative for metastatic malignancy (0/7).

I. Subcarinal lymph node (FS), resection:

Six lymph nodes, negative for metastatic malignancy (0/6).

Frozen section diagnosis is confirmed.

J. Peribronchial lymph node, resection: One lymph node, negative for metastatic malignancy (0/1).

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Intraoperative Consult Diagnosis:

FSA: Chest wall margin:

Negative for malignancy.

FSB: Pleural margin:

Negative for malignancy.

F/S TAT: 18 mins.

FSC: Right upper lobe bronchial margin:

Negative for malignancy.

F/S TAT: 7 mins.

FSE: Level II lymph node:

Negative for malignancy.

F/S TAT: 12 mins.

FSI: Subcarinal lymph node:

FSI1: Three nodes:

Negative for malignancy.

[page 3 of 5]
FSI2: Two nodes:

Negative for malignancy.

FSI3: One node bisected:

Negative for malignancy.

F/S TAT: 26 mins.

Gross Description:

Received are ten containers labeled with patient's name.

Part A received fresh for intraoperative examination, additionally labeled "chest wall margin" and consists of a 1.0 x 1.4 x 0.6 cm yellow-tan, irregular soft tissue with focal cautery on one side. The specimen is submitted for frozen section diagnosis and is completely resubmitted in cassette A1.

Part B is received fresh for intraoperative examination and additionally labeled "pleural margin" and consists of a 2.2 x 0.5 x 0.3 cm portion of pink-tan to yellow-tan, gelatinous soft tissue. The specimen is submitted for frozen section diagnosis and is completely resubmitted in cassette B1.

Part C is received fresh for intraoperative examination and additionally labeled "right upper lobe bronchial margin" and consists of a pink-tan, cylindrical soft tissue with a diameter of 1.4 cm, excised to a depth of 0.3 cm. The specimen is submitted for frozen section diagnosis and is completely resubmitted in cassette C1.

Part D is received in formalin additionally labeled "right upper and middle lobe."

Specimen components and dimensions: The specimen consists of the right upper and middle lobes. There is a portion of attached parietal pleura with dimensions of 6.2 x 5.0 cm. This parietal pleura is located on the upper lobe. The specimen has dimensions of 14.0 x 10.8 x 5.5 cm. The external surface of the lung is purple-tan and wrinkled. The specimen has been previously inked in black focally and incised. A portion of the specimen is sent to the Tissue Bank and is also sent fresh for diagnostics. There are two staple lines. These staple lines are removed and the underlying parenchyma is inked in black. The external pleural surface is inked in black.

Size, appearance, and location of tumor: Within the right upper lobe, there is a poorly circumscribed, white tan, irregular diffusely necrotic mass. The mass has dimensions of 6.5 x 4.8 x 7.5 cm. The tumor does appear to extend into the right middle lobe.

Distance to bronchial margin: 0.5 cm. The mass does not appear to grossly invade the bronchus. The mass appears to extend to the cauterized soft tissue edge in the hilum.

Distance to pleural surface: The mass appears to abut the pleural surface.

The mass appears to grossly abut the attached parietal pleura.

Number & appearance of peribronchial lymph nodes: There are hilar lymph nodes

[page 4 of 5]
identified, ranging in size from 0.6 to 1.6 cm. All of these are white-tan and appear anthracotic.

Other findings: There are no other gross pathologic findings identified.

Uninvolved lung: The remaining lung is red-tan and spongy.

Blocks submitted:

- D1 right middle lobe bronchial margin and vascular margins;
- D2 mass to pleura;
- D3 mass to bronchus;
- D4 mass to parietal pleura;
- D5 mass to inked hilar soft tissue edge;
- D6 additional representative section of mass;
- D7 uninvolved right upper lobe;
- D8 uninvolved right middle lobe;
- D9 one lymph node, bisected;
- D10 one lymph node, bisected;
- D11-12 multiple whole lymph nodes.

Part E is received fresh for intraoperative examination additionally labeled "level II lymph node" and consists of two gray-tan, lobular lymph nodes, 0.9 and 1.2 cm in greatest dimension. The specimen is submitted for frozen section diagnosis and is completely resubmitted in cassette E1.

Part F is received in formalin additionally labeled "inferior pulmonary lymph node" and consists of a single pink-tan rubbery lymph node, 0.6 cm in greatest dimension. The specimen is submitted in toto in cassette F1.

Part G is received in formalin additionally labeled "4R lower paratracheal lymph node" and consists of a 3.5 x 2.2 x 1.0 cm portion of yellow-tan, irregular fatty tissue. Sectioning the specimen reveals multiple pink-tan, rubbery lymph nodes, ranging from 0.4 to 2.2 cm in greatest dimension.

The specimen is submitted as follows:

- G1 one lymph node, bisected;
- G2 one lymph node, bisected;
- G3 one lymph node, bisected;
- G4 multiple whole lymph nodes.

Part H is received in formalin additionally labeled "2R upper paratracheal lymph node" and consists of a 5.2 x 2.6 x 1.2 cm portion of pink-tan, lobular fatty tissue. Sectioning the specimen reveals multiple pink-tan, rubbery lymph nodes, ranging from 0.5 to 1.8 cm in greatest dimension.

The specimen is submitted as follows:

- H1 one lymph node, bisected;
- H2 one lymph node, bisected;
- H3 one lymph node, bisected;

[page 5 of 5]
- H4 one lymph node, bisected;
- H5 multiple whole lymph nodes.

Part I is received fresh for intraoperative examination additionally labeled "subcarinal lymph node" and consists of six pink-tan, rubbery lymph nodes ranging in size from 0.5 to 1.4 cm.

The specimen is submitted for frozen section diagnosis and is completely resubmitted as follows:

- I1 three whole lymph nodes;
- I2 two whole lymph nodes;
- I3 one lymph node, bisected.

Part J is received in formalin additionally labeled "peribronchial lymph node" and consists of a single red-tan, irregular possible lymph node, 1.5 x 1.5 x 0.8 cm.

The specimen is submitted as follows:

- J1 entire specimen, trisected.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

[REDACTED]

END OF REPORT

Source: NCI Genomic Data Commons file ddcd5060-0ff6-4741-85a4-877a685b839f (TCGA-90-6837.65CA38C2-7497-4DEE-A054-5D2687171928.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).